Somatic mutation profile of tumor specimen TARGET-10-PARAXH-09A (aliquot TARGET-10-PARAXH-09A-01D) from TARGET case TARGET-10-PARAXH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,376 days).
Specimen TARGET-10-PARAXH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ffe680b-a6b3-4344-8cde-e26345ae0cb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAXH-10A (Blood Derived Normal), aliquot TARGET-10-PARAXH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbf898c1-fd95-4dfa-8e81-dbda31277d8f

The open-access MAF lists 54 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Intron 8, Silent 7, Nonsense Mutation 7, 3'UTR 4, RNA 1, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1976C>T p.T659M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59247923; called by muse, mutect2, varscan2
- CARD14 | c.348C>T p.S116= | Splice Region (SNP) | VAF 16/117 reads (14%) | catalogued as rs775819149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC42BPG | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs145169186; called by muse, mutect2, varscan2
- DIRAS1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.66); catalogued as rs1410258162; called by muse, mutect2, varscan2
- MMP20 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV52773658; called by muse, mutect2, varscan2
- NR2C2 | c.1288G>A p.G430S (on ENST00000393102; = p.G449S on NM_003298.5) | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100038183; called by muse, mutect2, varscan2
- SNX14 | c.1022G>C p.R341T (on ENST00000314673 / NM_001350535.1; = p.R297T on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs1438747848; called by muse, mutect2, varscan2
- TRPM3 | c.734G>A p.R245Q (on ENST00000357533 / NM_001366142.2; = p.R90Q on NM_020952.6) | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.21); catalogued as rs772042718, COSV100624473; called by muse, mutect2, varscan2
- TTN | c.86305C>A p.P28769T (on ENST00000591111; = p.P21345T on NM_003319.4) | Missense Mutation (SNP) | VAF 9/126 reads (7%) | PolyPhen benign (0.242); catalogued as COSV100623931; called by muse, mutect2
- USH2A | c.7795C>T p.Q2599* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as COSV56432114; called by muse, mutect2
- ZC2HC1C | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | catalogued as COSV53172490; called by muse, mutect2
- ABCC9 | c.3901C>G p.Q1301E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2
- ADAM19 | c.2668C>T p.Q890* | Nonsense Mutation (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- CD101 | c.2660C>G p.S887* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- CD44 | c.1531C>G p.Q511E | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- DRC1 | c.442A>G p.R148G | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.168); called by muse, mutect2
- FRMPD4 | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.345); called by muse, mutect2
- GABRA1 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GIGYF1 | c.2895G>C p.Q965H | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2
- GIGYF1 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- GPR158 | c.2112G>A p.W704* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- MMUT | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); called by muse, mutect2
- NBEA | c.191C>A p.S64* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- PLAA | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- PTCHD1 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- SPTB | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SSR2 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC79 | c.2944C>G p.L982V (on ENST00000393151 / NM_001346218.2; = p.L805V on NM_020818.5) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- WDTC1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC2HC1C | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF43 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF490 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA6 | c.708T>C p.Y236= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- DCAF8L2 | c.654C>T p.F218= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- GPR149 | c.636C>G p.L212= | Silent (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- LMO4 | c.180C>T p.I60= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV65170115; called by muse, mutect2
- NFATC2IP | c.1167C>G p.L389= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs374516541; called by muse, mutect2, varscan2
- RRN3 | c.81G>A p.S27= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs753953182; called by muse, mutect2, varscan2
- SLC5A9 | c.1074C>T p.I358= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- ABCC12 | c.1712+137C>A | Intron (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- CD101 | c.2824+65C>T | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- CD109 | c.*4488C>A | 3'UTR (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- CTSC | c.889+16C>G | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- FAM183BP | n.1205G>A | RNA (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- H1-5 | c.*41C>G | 3'UTR (SNP) | VAF 4/35 reads (11%) | catalogued as rs1412473921; called by muse, varscan2
- IL32 | c.253-153G>C | Intron (SNP) | VAF 3/24 reads (13%) | catalogued as rs1159981158; called by muse, mutect2
- LDB2 | c.892-179C>T | Intron (SNP) | VAF 8/52 reads (15%) | catalogued as COSV58772204; called by muse, mutect2, varscan2
- MAP3K13 | c.2431-204C>T | Intron (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- NPR3 | c.*3307C>G | 3'UTR (SNP) | VAF 23/194 reads (12%) | called by muse, mutect2, varscan2
- NUP62CL | c.*164C>G | 3'UTR (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- SEL1L | c.-9G>A | 5'UTR (SNP) | VAF 5/55 reads (9%) | catalogued as rs1301405892, COSV60923404; called by muse, mutect2
- SERGEF | c.1048+31485G>C | Intron (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- TMEM132E | chr17:34577457 G>A | 5'Flank (SNP) | VAF 15/88 reads (17%) | catalogued as rs550234036; called by muse, mutect2, varscan2
- UNC80 | c.7808+28C>A | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
